Surgical pathology report (de-identified scan), TCGA case TCGA-A7-A6VX, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-A7-A6VX-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3

Carcinoma, infiltrating duct NOS
8500/3

Site (L) Breast NOS
C50.9

7/25/13

Final Surgical Pathology Report

Procedure:

Diagnosis

- A. Left axillary sentinel lymph node, excision:
No evidence of metastasis in 2 lymph nodes (0/2).
- B. Left breast, excisional biopsy:
Infiltrating ductal carcinoma, grade 3, 2.5 cm, extending to within 0.5 mm from the inferior margin of resection.
Ductal carcinoma in situ, comedo and solid subtypes, nuclear grade 3 with necrosis, extending to posterior margin.

Microscopic Description:

Microscopic examination performed.

- A. Sections of the left axilla sentinel lymph node demonstrate 2 lymph nodes with no evidence of metastasis. The nodes are examined by multilevel sectioning with hematoxylin and eosin, as well as by immunohistochemistry for pankeratin

B. Invasive Carcinoma:

Histologic type: infiltrating ductal carcinoma

Histologic grade:

Overall grade: 3

Architectural score: 3

Nuclear score: 3

Mitotic score: 2

Greatest dimension (pT): 2.5 cm, pT2

Specimen margins: extremely close, < 0.5 mm to black ink,
(inferior margin)

Vessel invasion: not identified

Calcification: present

Ductal carcinoma in situ:

Histologic pattern: comedo and solid

Nuclear grade: 3

Central Necrosis: present

% DCIS of total tumor (if mixed): < 10%

Extensive intraductal component (present/absent): absent

Specimen margins: positive, in situ carcinoma at orange ink (posterior margin)

Prognostic markers: see outside report

Specimen

- A. Left axillary sentinel node
B. Left breast biopsy long suture anterior short superior

Clinical Information

year-old black female with left breast cancer

Gross Description

- A. Received fresh labeled "left axillary sentinel node" is a 3.4 x 3.0 x 1.5 cm portion of soft, lobulated tan gold adipose tissue which contains two rubbery tan-pink tissues in keeping with lymph nodes averaging 1.4 cm in greatest dimension. The lymphoid tissues are bisected and entirely submitted independently in 2 blocks.

[page 2 of 2]
B. Received fresh and subsequently placed in formalin at _____ labeled "left breast biopsy" is a 6.2 cm (medial to lateral) by 5.3 cm (anterior to posterior) by 3.0 cm (superior to inferior) soft, lobulated tan-white-gold portion of fibroadipose tissue with 2 sutures as stated previously. The margins are inked as follows: Superior blue, inferior black, anterior green, and posterior orange. The specimen is sectioned from medial to lateral. There is a 2.5 cm (medial to lateral) by 2.0 cm (anterior to posterior) by 1.9 cm (superior to inferior) rubbery tan-white tumor mass within the lateral half of the specimen. The tumor focally approaches the superior margin to within 0.2 cm. The remaining cut surfaces consist predominantly of soft, lobulated tan gold adipose tissue with a scant amount of interspersed delicate tan-white fibrous tissue. A representative portion of tumor and a representative portion of normal parenchyma are submitted for tissue procurement as requested.

Summary: 1 - perpendicular sections medial margin, 2 through 9 - sequential sections including entire lesion, 10 - perpendicular sections lateral margin

Source: NCI Genomic Data Commons file 9dce4c58-bd33-41ae-9bca-dd775a164d3c (TCGA-A7-A6VX.80EDDCAC-B87B-47E6-A48C-F166D227DA6C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).